FM case AD138 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Cervix uteri.
https://portal.gdc.cancer.gov/cases/4750ef95-4203-4419-9b1a-497fa484376f

Female, 55.6 years: Neuroendocrine carcinoma, NOS (ICD-O-3 8246/3) of the cervix uteri; metastasis biopsied or resected from the vagina. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
